TCGA case TCGA-04-1347 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Gynecologic Oncology Group. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f0c353fd-947c-41e2-b643-3ecc0d69796c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 81 years; Vital status: Alive.

Diagnoses (1)
1. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 81.3 years (29,695 days); Year of diagnosis: 2004; Method of diagnosis: Cytology; FIGO stage: Stage IV; Tumor grade: G3; Prior treatment: No; Days to last follow up: 1,919 days (5.3 years).
   Pathology details: Lymphatic invasion present: No; Residual tumor measurement: No macroscopic disease; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 19 days; Days to treatment end: 173 days; Number of cycles: 6; Treatment dose: 2,400 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 19 days; Days to treatment end: 173 days; Number of cycles: 2; Treatment dose: 750 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Treatment intent type: Adjuvant; Days to treatment start: 19 days; Days to treatment end: 173 days; Number of cycles: 2; Treatment dose: 200 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 19 days; Days to treatment end: 173 days; Number of cycles: 6; Treatment dose: 1,764 mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 1,919 days (5.3 years); Disease response: Tumor Free.
- Karnofsky performance status: 100; ECOG performance status: 0; Timepoint: Preoperative.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-04-1347-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.1; Intermediate dimension: 1; Shortest dimension: 0.1.
  Slide TCGA-04-1347-01A-01-TS1: Section location: Top; Percent tumor cells: 93; Percent tumor nuclei: 99; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 5.
  Slide TCGA-04-1347-01A-01-BS1: Section location: Bottom; Percent tumor cells: 55; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 40.
- Sample TCGA-04-1347-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2; Intermediate dimension: 1.5; Shortest dimension: 0.2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: Tumor free; History neoadjuvant treatment: No; Method initial path diagnosis: Cytology (e.g. Peritoneal or pleural fluid); Lymphovascular invasion indicator: No.
- Drug treatment 1: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 4: Pharmaceutical therapy drug name: Taxotere.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free.

The TCGA Pan-Cancer Clinical Data Resource (Liu et al., Cell 2018) lists this case as redacted by TCGA at the time of its curation; its follow-up endpoints are therefore not restated here.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-04-1347-01A-01D-0428-01): tumor purity 0.94, ploidy 4.29, whole-genome doublings 2.
